Somatic mutation profile of cancer-model specimen HCM-BROD-0719-C43-85N (Adherent Cell Line, passage 8; aliquot HCM-BROD-0719-C43-85N-01D-A85K-36), derived from the metastatic tumor of HCMI case HCM-BROD-0719-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 66.3 years (24,230 days).
Specimen HCM-BROD-0719-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 188f0952-df31-40d9-8515-b1e9b99286b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0719-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0719-C43-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0f83a6b-ddde-421c-b261-9e1b25479cda

The open-access MAF lists 39 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 26, Silent 9, Frame Shift Del 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAA2 | c.211A>G p.R71G | Missense Mutation (SNP) | VAF 103/273 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390174167; called by muse, mutect2, varscan2
- ALG1L | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs770366017, COSV61076377; called by muse, mutect2, varscan2
- C6orf118 | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 90/509 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57812202; called by muse, mutect2, varscan2
- PDZRN4 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 37/272 reads (14%) | catalogued as COSV68402795; called by muse, mutect2, varscan2
- PLA2G6 | c.66C>A p.F22L | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.13); catalogued as COSV59268104; called by muse, mutect2
- RNASET2 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 20/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1391650191; called by muse, mutect2
- SEZ6L | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764504144, COSV99962276; called by muse, mutect2, varscan2
- TMEM63C | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 122/418 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs374759104; called by muse, mutect2, varscan2
- TRAPPC9 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 134/449 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.606); catalogued as rs754722286, COSV66894358; called by muse, mutect2, varscan2
- B3GALT4 | c.703A>T p.N235Y | Missense Mutation (SNP) | VAF 28/961 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CT47B1 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 106/439 reads (24%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DDX10 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 86/356 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ERBB3 | c.722C>G p.T241R | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, mutect2, varscan2
- FAP | c.1544A>T p.E515V | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2
- GRAMD1B | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 96/488 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, varscan2
- LAG3 | c.185C>G p.T62S | Missense Mutation (SNP) | VAF 59/433 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- MACC1 | c.601A>T p.S201C | Missense Mutation (SNP) | VAF 130/534 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MECOM | c.209A>G p.E70G (on ENST00000468789 / NM_001105078.4; = p.E258G on NM_004991.4) | Missense Mutation (SNP) | VAF 50/385 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC16 | c.14630C>T p.P4877L | Missense Mutation (SNP) | VAF 87/334 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- NF1 | c.3632T>C p.L1211P | Missense Mutation (SNP) | VAF 145/451 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NHSL2 | c.125_135del p.S42Kfs*2 (on ENST00000510661; = p.S408Kfs*2 on NM_001013627.2) | Frame Shift Del (DEL) | VAF 46/175 reads (26%) | called by mutect2, pindel, varscan2
- OR1S2 | c.872T>C p.F291S | Missense Mutation (SNP) | VAF 141/516 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR4P4 | c.205del p.L69Ffs*7 | Frame Shift Del (DEL) | VAF 141/524 reads (27%) | called by mutect2, pindel, varscan2
- PDGFD | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 19/407 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RYR2 | c.12911G>C p.G4304A | Missense Mutation (SNP) | VAF 36/491 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); called by muse, mutect2
- SACS | c.12424A>G p.K4142E | Missense Mutation (SNP) | VAF 113/365 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SCN11A | c.4472T>A p.M1491K | Missense Mutation (SNP) | VAF 59/421 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SRGAP2C | c.1377T>G p.F459L | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- STK10 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 142/515 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- WFDC12 | c.275del p.P92Lfs*58 | Frame Shift Del (DEL) | VAF 66/446 reads (15%) | called by mutect2, pindel, varscan2
- APC2 | c.786G>A p.E262= | Silent (SNP) | VAF 186/551 reads (34%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.885G>A p.V295= | Silent (SNP) | VAF 149/484 reads (31%) | called by muse, mutect2, varscan2
- DCPS | c.1005G>A p.Q335= | Silent (SNP) | VAF 55/292 reads (19%) | called by muse, varscan2
- GLT1D1 | c.462A>G p.Q154= | Silent (SNP) | VAF 44/362 reads (12%) | called by muse, mutect2, varscan2
- HAO1 | c.921C>T p.G307= | Silent (SNP) | VAF 120/468 reads (26%) | catalogued as rs748303742, COSV66493781; called by muse, mutect2, varscan2
- LRP1B | c.5877T>G p.A1959= | Silent (SNP) | VAF 70/279 reads (25%) | catalogued as rs752789772; called by muse, mutect2, varscan2
- PLD1 | c.1488C>T p.D496= | Silent (SNP) | VAF 131/471 reads (28%) | catalogued as rs770287345; called by muse, mutect2, varscan2
- SCN5A | c.2496C>T p.I832= | Silent (SNP) | VAF 51/390 reads (13%) | catalogued as rs761287478, COSV61116092; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZMIZ1 | c.1269G>A p.Q423= | Silent (SNP) | VAF 220/511 reads (43%) | called by muse, mutect2, varscan2
